MMRF case MMRF_1900 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/633aa310-32d7-4d53-9abd-ef127b6cf328

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.6 years (28,350 days); ISS stage: III; Days to last known disease status: 1,002 days (2.7 years); Days to last follow up: 1,002 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 405 days (1.1 years); Days to treatment end: 539 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 614 days (1.7 years); Days to treatment end: 708 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 925 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -43 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 34.3 mg/dL; Immunoglobulin G 41.8 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 8.2 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 9.8 g/dL; Glucose 6.22 mmol/L.
- Day 71: M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.46 mg/dL; Immunoglobulin G 31.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 8.3 g/dL; Glucose 7.21 mmol/L.
- Day 141 (ECOG 1): Hemoglobin 6.2 mmol/L; Leukocytes 8.5 ×10⁹/L; Platelets 294 ×10⁹/L.
- Day 218 (ECOG 2): Hemoglobin 6.14 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.21 ×10⁹/L; Platelets 241 ×10⁹/L.
- Day 288 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.
- Day 407: M Protein 1.31 g/dL; Beta 2 Microglobulin 4.8 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Total Protein 7.2 g/dL.
- Day 489 (ECOG 2): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.07 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 6.33 mmol/L.
- Day 595 (ECOG 1): M Protein 1.25 g/dL; Hemoglobin 7.07 mmol/L; Leukocytes 6.1 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 133 µmol/L.
- Day 708 (ECOG 2): M Protein 0.7 g/dL; Beta 2 Microglobulin 3.17 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL.
- Day 771 (ECOG 2): M Protein 1.35 g/dL; Beta 2 Microglobulin 5 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 6.1 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 6.11 mmol/L.
- Day 834 (ECOG 2): M Protein 0.9 g/dL; Hemoglobin 6.82 mmol/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Albumin 32 g/L.
- Day 960 (ECOG 2): M Protein 1.09 g/dL; Hemoglobin 6.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Albumin 33 g/L.
- Day 1,002 (ECOG 2): Hemoglobin 6.26 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 319 ×10⁹/L.

Other clinical attributes
- Day -43: Weight: 125 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1900_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -43 days.
- Sample MMRF_1900_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -43 days.
